Somatic mutation profile of tumor specimen 0DNHH4 from CCDI case PBCBUD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 5.5 years (2,001 days).
Specimen 0DNHH4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dc29e6d-bfe2-4092-84a1-a4535bb82c63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNHGS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e3cadb-b7a1-49c3-955d-2aa8c964c3e4

The open-access MAF lists 45 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 6, 3'UTR 3, 5'UTR 1, 3'Flank 1, Splice Region 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD1 | c.2497-5dup | Splice Region (INS) | VAF 129/1092 reads (12%) | catalogued as rs1333454417; called by mutect2, varscan2
- CYS1 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 614/1326 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368468153; called by muse, mutect2, varscan2
- DOCK9 | c.579G>A p.M193I (on ENST00000376460 / NM_001366676.2; = p.M194I on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/907 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.174); catalogued as COSV99044626; called by muse, mutect2, varscan2
- DSCAML1 | c.3238C>T p.R1080W (on ENST00000321322; = p.R1020W on NM_020693.4) | Missense Mutation (SNP) | VAF 113/861 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1034319646, COSV58386656; called by muse, mutect2, varscan2
- FGD5 | c.2242C>T p.R748C | Missense Mutation (SNP) | VAF 130/670 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776528093; called by muse, mutect2, varscan2
- FUT1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 132/815 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM942060; called by muse, mutect2, varscan2
- MPL | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 32/954 reads (3%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.554); catalogued as COSV65245565; called by muse, mutect2
- REST | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 115/1152 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as CM1513327, COSV100470822; called by muse, mutect2, varscan2
- SLCO5A1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 106/1636 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs776943828, COSV52653397; called by muse, mutect2
- ZSCAN5B | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 136/931 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs534584381, COSV61999708; called by muse, mutect2, varscan2
- ARFGEF3 | c.6406A>G p.T2136A | Missense Mutation (SNP) | VAF 65/1093 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.024); called by muse, mutect2
- CHRDL1 | c.1101G>C p.Q367H (on ENST00000372045; = p.Q373H on NM_145234.4) | Missense Mutation (SNP) | VAF 77/566 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- COL18A1 | c.1206_1217del p.A404_P407del | In Frame Del (DEL) | VAF 146/963 reads (15%) | called by mutect2, pindel, varscan2
- GPM6A | c.440T>A p.F147Y | Missense Mutation (SNP) | VAF 265/1199 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ISOC1 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 38/676 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); called by muse, mutect2
- JADE2 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 116/943 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LAMB2 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 178/1081 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MMS22L | c.2184G>T p.Q728H | Missense Mutation (SNP) | VAF 211/1072 reads (20%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.904); called by mutect2, varscan2
- POLR1D | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 198/980 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP4R1 | c.2041C>G p.R681G (on ENST00000400556 / NM_001042388.3; = p.R664G on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 464/1183 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TTC6 | c.158A>T p.N53I (on ENST00000267368; = p.N1322I on NM_001310135.3) | Missense Mutation (SNP) | VAF 208/1387 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.051); called by muse, mutect2
- XDH | c.54A>T p.K18N | Missense Mutation (SNP) | VAF 146/1299 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ZNF658 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 146/992 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ANP32B | c.480C>T p.A160= | Silent (SNP) | VAF 181/1171 reads (15%) | catalogued as rs144253360; called by muse, mutect2, varscan2
- CYP2J2 | c.993A>C p.P331= | Silent (SNP) | VAF 44/1436 reads (3%) | called by muse, mutect2
- GALK2 | c.1011C>T p.S337= | Silent (SNP) | VAF 174/880 reads (20%) | catalogued as rs771720042; called by muse, mutect2, varscan2
- HLA-DOA | c.411C>T p.N137= | Silent (SNP) | VAF 128/750 reads (17%) | called by muse, mutect2, varscan2
- HTRA4 | c.318C>T p.C106= | Silent (SNP) | VAF 34/932 reads (4%) | called by muse, mutect2
- LRRC8E | c.927C>T p.F309= | Silent (SNP) | VAF 153/887 reads (17%) | catalogued as COSV100142553; called by muse, mutect2, varscan2
- MED13 | c.3936A>G p.Q1312= | Silent (SNP) | VAF 161/951 reads (17%) | catalogued as rs759324265; called by muse, mutect2, varscan2
- MYH7B | c.768G>T p.T256= | Silent (SNP) | VAF 121/715 reads (17%) | called by muse, mutect2, varscan2
- PTPRB | c.1743C>T p.D581= | Silent (SNP) | VAF 421/1374 reads (31%) | catalogued as rs368648598; called by muse, mutect2, varscan2
- SEL1L3 | c.1704A>G p.G568= | Silent (SNP) | VAF 51/1153 reads (4%) | called by muse, mutect2
- AHCTF1 | c.-94C>T | 5'UTR (SNP) | VAF 50/1174 reads (4%) | called by muse, mutect2
- AL450447.1 | n.891G>A | RNA (SNP) | VAF 190/1193 reads (16%) | called by muse, mutect2, varscan2
- CPA1 | c.787+37G>A | Intron (SNP) | VAF 71/555 reads (13%) | called by muse, mutect2, varscan2
- CYP4X1 | c.1073+25C>A | Intron (SNP) | VAF 119/621 reads (19%) | called by muse, mutect2, varscan2
- DBX2 | c.*17G>A | 3'UTR (SNP) | VAF 183/1240 reads (15%) | catalogued as rs768260068, COSV60337144; called by muse, mutect2, varscan2
- DCC | c.*3946G>A | 3'UTR (SNP) | VAF 28/992 reads (3%) | called by muse, mutect2
- DYNC2I2 | c.703+61G>T | Intron (SNP) | VAF 134/758 reads (18%) | called by muse, mutect2, varscan2
- OR52I2 | c.*17G>A | 3'UTR (SNP) | VAF 125/620 reads (20%) | called by muse, mutect2, varscan2
- PI4KA | c.5923+71C>T | Intron (SNP) | VAF 56/116 reads (48%) | catalogued as rs1357537307; called by muse, mutect2, varscan2
- SKIV2L | c.3399+14C>T | Intron (SNP) | VAF 92/539 reads (17%) | catalogued as rs945454349; called by muse, mutect2, varscan2
- UBE2I | c.334-62G>T | Intron (SNP) | VAF 118/594 reads (20%) | called by muse, mutect2, varscan2
- USP34 | chr2:61186150 T>C | 3'Flank (SNP) | VAF 52/620 reads (8%) | called by muse, mutect2
